Gene-level copy-number profile of tumor specimen HCM-CSHL-0379-C18-01B from HCMI case HCM-CSHL-0379-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.3 years (26,410 days).
Specimen HCM-CSHL-0379-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file edfd61b7-2598-443d-8ffd-02864ce91a39.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0379-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/1499e7b0-7932-4507-b4e6-29d1a8e53224

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 133; copy number 1: 17,434; copy number 2: 36,035; copy number 3: 5,089; copy number 4: 34; copy number 5: 2; copy number 6: 15; copy number 8: 1; copy number 9: 1; copy number 11: 21; copy number 13: 4; copy number 18: 129.

Homozygous deletions (total copy number 0; autosomes only): 127 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,974,502–17,011,928, 5 genes: MFAP2, AL049569.2, AL049569.1, ATP13A2, AL049569.3.
- chr1:28,812,142–28,881,835, 3 genes: OPRD1, AL009181.1, Y_RNA.
- chr1:55,039,447–55,064,852, 1 gene: PCSK9.
- chr2:95,274,449–95,291,308, 1 gene: PROM2.
- chr2:104,865,407–104,872,595, 1 gene (within-gene range 0–2): LINC01159.
- chr2:119,156,243–119,170,115, 2 genes: C1QL2, RN7SL468P.
- chr2:232,525,993–232,548,115, 2 genes (within-gene range 0–2): CHRND, CHRNG.
- chr3:47,818,005–47,818,128, 1 gene (within-gene range 0–2): AC026318.1.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr4:54,221,126–54,221,472, 1 gene (within-gene range 0–2): RPL22P13.
- chr4:183,037,665–183,040,119, 1 gene: CIBAR1P2.
- chr5:132,060,655–132,080,133, 3 genes: IL3, CSF2, AC034216.1.
- chr8:28,299,683–28,300,566, 1 gene (within-gene range 0–1): RPL5P22.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:121,494,519–121,494,821, 1 gene (within-gene range 0–1): RN7SL187P.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–1): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–1): MIR601.
- chr11:66,480,013–66,568,879, 8 genes (within-gene range 0–2): DPP3, AP002748.5, BBS1, AP002748.6, ZDHHC24, ACTN3, AP002748.2, CTSF.
- chr11:125,442,881–125,592,568, 1 gene (within-gene range 0–2): FEZ1.
- chr12:54,058,254–54,125,992, 5 genes: FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA.
- chr15:25,172,635–25,211,877, 22 genes (within-gene range 0–1): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23.
- chr15:25,228,967–25,250,940, 13 genes (within-gene range 0–1): SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:89,358,841–89,496,589, 5 genes: AC133637.1, AC133637.2, MIR9-3HG, MIR9-3, RHCG.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:17,504,005–17,591,708, 4 genes (within-gene range 0–1): AC020558.6, PEMT, AC020558.2, RNU6-468P.
- chr18:37,234,119–37,762,131, 7 genes (within-gene range 0–1): AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr18:46,326,809–46,463,140, 3 genes: RNF165, AC015959.1, AC018931.1.
- chr19:4,502,180–4,518,465, 1 gene (within-gene range 0–2): PLIN4.
- chr19:37,007,857–37,130,368, 4 genes (within-gene range 0–1): ZNF420, AC010632.3, AC010632.1, AC010632.2.
- chr19:58,012,589–58,025,926, 2 genes: VN2R19P, AC008969.2.
- chr22:18,110,331–18,611,919, 19 genes (within-gene range 0–1): TUBA8, AC008079.1, USP18, FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.
- chr22:32,188,400–32,205,001, 3 genes: AL008723.3, RFPL2, IGLCOR22-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 173 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:629,239–667,833, 6 genes, copy number 6 (within-gene range 3–6): WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2.
- chr16:678,504–692,554, 6 genes, copy number 6 (within-gene range 3–6): LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1.
- chr17:3,977,103–3,981,899, 1 gene, copy number 5: LINC01975.
- chr17:18,497,095–18,551,705, 4 genes, copy number 13 (within-gene range 2–13): NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr17:36,253,456–36,944,612, 19 genes, copy number 11 (within-gene range 2–11): TBC1D3I, TBC1D3H, RNU6-1192P, TBC1D3F, TBC1D3J, ZNHIT3, RNA5SP439, MYO19, PIGW, GGNBP2, AC243732.1, DHRS11, MRM1, AC243830.2, AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1.
- chr17:38,297,023–40,975,926, 131 genes, copy number 11–18 (broad region; genes not listed).
- chr19:859,664–863,641, 1 gene, copy number 6: CFD.
- chr19:43,153,279–43,160,862, 1 gene, copy number 8: AC005392.1.
- chr21:43,446,601–43,479,534, 3 genes, copy number 5–9: LINC00319, LINC00313, AP001048.1.
- chr22:18,733,914–18,757,906, 1 gene, copy number 6: FAM230E.

Autosomal genes at a single copy (total copy number 1): 14,616. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
